MMRF case MMRF_1607 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/8d708af1-fcc9-49c1-8c76-d797b2160031

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 57 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 57.5 years (20,990 days); ISS stage: I; Days to last known disease status: 1,253 days (3.4 years); Days to last follow up: 1,253 days (3.4 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 203 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 113 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 113 days; Days to treatment end: 190 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 141 days; Days to treatment end: 190 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 203 days; Days to treatment end: 203 days.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 1,253.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 1 (ECOG 0): M Protein 1.9 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 14.7 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.53 mg/dL; Immunoglobulin G 25.6 g/L; Immunoglobulin A 1.03 g/L; Immunoglobulin M 0.54 g/L; Beta 2 Microglobulin 3.3 µg/mL; Lactate Dehydrogenase 2.87 µkat/L; Hemoglobin 7.19 mmol/L; Leukocytes 4.5 ×10⁹/L; Absolute Neutrophil 2.3 ×10⁹/L; Platelets 250 ×10⁹/L; Creatinine 159 µmol/L; Blood Urea Nitrogen 8.93 mmol/L; Calcium 2.53 mmol/L; Albumin 43 g/L; Total Protein 8.7 g/dL; Glucose 12.4 mmol/L; C-Reactive Protein 0.016 mg/dL.
- Day 99 (ECOG 1): M Protein 0.6 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 7.72 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.22 mg/dL; Immunoglobulin G 13.3 g/L; Immunoglobulin A 1.23 g/L; Immunoglobulin M 0.57 g/L; Hemoglobin 7.69 mmol/L; Leukocytes 8.3 ×10⁹/L; Absolute Neutrophil 6.9 ×10⁹/L; Platelets 240 ×10⁹/L; Creatinine 159 µmol/L; Blood Urea Nitrogen 10.7 mmol/L; Calcium 2.55 mmol/L; Albumin 45 g/L; Total Protein 8.1 g/dL; Glucose 9.96 mmol/L.
- Day 190 (ECOG 0): M Protein 0.6 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 7 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.54 mg/dL; Immunoglobulin G 13.5 g/L; Immunoglobulin A 1.64 g/L; Immunoglobulin M 0.55 g/L; Hemoglobin 7.07 mmol/L; Leukocytes 6.2 ×10⁹/L; Absolute Neutrophil 4.7 ×10⁹/L; Platelets 136 ×10⁹/L; Creatinine 118 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.3 mmol/L; Glucose 9.57 mmol/L.
- Day 282 (ECOG 0): M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.24 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.11 mg/dL; Immunoglobulin G 9.64 g/L; Immunoglobulin A 0.25 g/L; Immunoglobulin M 0.25 g/L; Hemoglobin 5.7 mmol/L; Leukocytes 5.1 ×10⁹/L; Absolute Neutrophil 3.1 ×10⁹/L; Platelets 205 ×10⁹/L; Creatinine 131 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.38 mmol/L; Albumin 43 g/L; Total Protein 7 g/dL; Glucose 7.7 mmol/L.
- Day 358 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.74 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.85 mg/dL; Immunoglobulin G 11.1 g/L; Immunoglobulin M 1.5 g/L; Hemoglobin 8.68 mmol/L; Leukocytes 4.8 ×10⁹/L; Absolute Neutrophil 3.2 ×10⁹/L; Platelets 209 ×10⁹/L; Creatinine 139 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.7 mmol/L; Albumin 48 g/L; Total Protein 8.3 g/dL; Glucose 6.22 mmol/L.
- Day 471: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.22 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.78 mg/dL; Immunoglobulin G 12.8 g/L; Immunoglobulin A 1.64 g/L; Immunoglobulin M 0.39 g/L; Hemoglobin 7.56 mmol/L; Leukocytes 3.8 ×10⁹/L; Absolute Neutrophil 2.5 ×10⁹/L; Platelets 203 ×10⁹/L; Creatinine 132 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.43 mmol/L; Albumin 41 g/L; Total Protein 7.6 g/dL; Glucose 15.1 mmol/L.
- Day 560: Serum Free Immunoglobulin Light Chain, Kappa 4.25 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.94 mg/dL; Immunoglobulin G 14.5 g/L; Immunoglobulin A 1.86 g/L; Immunoglobulin M 0.45 g/L; Hemoglobin 8 mmol/L; Leukocytes 2.4 ×10⁹/L; Absolute Neutrophil 0.8 ×10⁹/L; Platelets 223 ×10⁹/L; Creatinine 129 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.5 mmol/L; Albumin 44 g/L; Total Protein 8 g/dL; Glucose 8.47 mmol/L.
- Day 660 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 4.54 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.89 mg/dL; Immunoglobulin G 14.7 g/L; Immunoglobulin A 1.97 g/L; Immunoglobulin M 0.48 g/L; Hemoglobin 7.69 mmol/L; Leukocytes 2.8 ×10⁹/L; Absolute Neutrophil 0.9 ×10⁹/L; Platelets 195 ×10⁹/L; Creatinine 137 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.4 mmol/L; Albumin 43 g/L; Total Protein 7.7 g/dL; Glucose 9.02 mmol/L.
- Day 751 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.56 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.91 mg/dL; Immunoglobulin G 14 g/L; Immunoglobulin A 1.95 g/L; Immunoglobulin M 0.5 g/L; Hemoglobin 7.44 mmol/L; Leukocytes 2.6 ×10⁹/L; Absolute Neutrophil 1.1 ×10⁹/L; Platelets 206 ×10⁹/L; Creatinine 137 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.33 mmol/L; Albumin 40 g/L; Total Protein 7.6 g/dL; Glucose 6.77 mmol/L.
- Day 849 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 6.17 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 4.44 mg/dL; Immunoglobulin G 14.1 g/L; Immunoglobulin A 2.24 g/L; Immunoglobulin M 0.53 g/L; Hemoglobin 8.06 mmol/L; Leukocytes 3.2 ×10⁹/L; Absolute Neutrophil 1.9 ×10⁹/L; Platelets 187 ×10⁹/L; Creatinine 134 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.43 mmol/L; Albumin 41 g/L; Total Protein 7.8 g/dL; Glucose 6.49 mmol/L.
- Day 975 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 5.99 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 4.56 mg/dL; Immunoglobulin G 15.9 g/L; Immunoglobulin A 2.36 g/L; Immunoglobulin M 0.57 g/L; Hemoglobin 7.32 mmol/L; Leukocytes 3 ×10⁹/L; Absolute Neutrophil 1.31 ×10⁹/L; Platelets 185 ×10⁹/L; Creatinine 165 µmol/L; Blood Urea Nitrogen 9.28 mmol/L; Calcium 2.38 mmol/L; Albumin 44 g/L; Total Protein 7.8 g/dL; Glucose 8.36 mmol/L.
- Day 1,129 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 11.8 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 6.8 mg/dL; Immunoglobulin G 15.2 g/L; Immunoglobulin A 2.64 g/L; Immunoglobulin M 0.83 g/L; Hemoglobin 6.7 mmol/L; Leukocytes 2.2 ×10⁹/L; Absolute Neutrophil 1.25 ×10⁹/L; Platelets 151 ×10⁹/L; Creatinine 193 µmol/L; Blood Urea Nitrogen 16.4 mmol/L; Calcium 2.5 mmol/L; Albumin 43 g/L; Total Protein 7.9 g/dL; Glucose 5.61 mmol/L.
- Day 1,226: Hemoglobin 7.13 mmol/L; Leukocytes 2.7 ×10⁹/L; Absolute Neutrophil 0.94 ×10⁹/L; Platelets 12.6 ×10⁹/L.

Other clinical attributes
- Day 1: Weight: 76 kg; Height: 180 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_1607_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 1 day.
- Sample MMRF_1607_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 1 day.
